CCDI case PBCCVR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/2643dc63-1d65-4228-a02a-14d3ba7c4559

Demographics
Sex at birth: male.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.8 years (6,125 days).

Biospecimens (4 samples)
- Sample 0DPE90: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPEA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Samples 0DQ2MY, 0DQ2NA (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
